Surgical pathology report (de-identified scan), TCGA case TCGA-08-0356, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0356-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA-08-0356

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, left temporal lobe, biopsy: WHO glioblastoma multiforme, grade IV; see comment.
- B. Brain, left temporal lobe, ultrasonic aspiration: WHO glioblastoma multiforme, grade IV; see comment.
- C. Brain, left temporal lobe, resection: WHO glioblastoma multiforme, grade IV; see comment.

COMMENT: This glioblastoma multiforme has well-developed areas of microvascular proliferation, foci of necrosis with pseudopalisading, and abundant mitotic figures.

Intraoperative Diagnosis

FS1 (A) Brain, temporal lobe, biopsy: WHO glioblastoma multiforme, grade IV. Tissue section and cytologic preparation. [REDACTED]

Gross Description

The specimen is received fresh in three parts, each labeled with the patient's name and medical record number.

Part A is additionally labeled "tumor." It consists of a single unoriented fragment of glistening, tan-pink soft tissue, measuring 0.6 x 0.5 x 0.3 cm. A portion of the specimen is submitted for frozen section diagnosis and cytologic preparation as FS1, with the frozen section remnant submitted in cassette A1. An additional portion of fresh tissue is saved in glutaraldehyde for possible future electron microscopy studies. The remainder of the tissue is submitted in cassette A2.

Part B, additionally labeled "2 - tumor from CUSA," consists of multiple soft, pink-tan, irregular, glistening, unoriented tissue fragments, received in a suction bottle, measuring 5.0 x 3.5 x 0.8 cm in aggregate. The

[page 2 of 2]
specimen is entirely submitted in cassettes B1-B8.

Part C, additionally labeled "3 - tumor," consists of one soft, pink-yellow, irregular, glistening, unoriented tissue fragment, measuring 0.8 x 0.4 x 0.2 cm. The specimen is entirely submitted in cassette C1.

Clinical History

The patient is a [REDACTED] with a left temporal lobe tumor.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file f49803c7-7340-4412-967e-70d67e50b9e7 (TCGA-08-0356.F4E9DC9C-6BE9-4D5F-A2B3-8F8FED67F482.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).